Surgical pathology report (de-identified scan), TCGA case TCGA-29-A5NZ, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-A5NZ-01A (Primary Tumor).

[page 1 of 3]
ICD-03

Adenocarcinoma, papillary Serous

Site: Specified parts of peritoneum

Omentum C48.1

920218/13

Surg Path

CLINICAL HISTORY:

Outside hospital left ovarian mass increased CA125, abdominal swelling.

GROSS EXAMINATION:

A. "Omentum", received fresh for frozen and placed in formalin on [REDACTED] at [REDACTED] is a 19 x 9 x 2 cm fragment of yellow adipose tissue that is firm, solid and multinodular. Sectioning of the specimen reveals a tan-yellow, firm parenchyma with some mucous. A representative section was submitted in frozen in AF1 and submitted in A1. Another representative section will be submitted as A2. A portion of the specimen was sent for research.

B. "Uterus, cervix, bilateral tubes and ovaries", received fresh and placed in formalin on [REDACTED] a 92.6 gram, previously opened hysterectomy specimen with uterus and cervix, bilateral tubes, and ovaries. The uterus is 4.5 cm from cornu to cornu, 2.1 cm from anterior to posterior, and 9.1 cm from superior to inferior. The cervix measures 2.7 cm in diameter with a 1.1 cm round patent os. The endometrium is grossly unremarkable. The anterior endometrium measures 1.1 cm from cornu to cornu and 4.5 cm in length. The posterior endometrium is 0.9 cm from cornu to cornu and 4.1 cm in length. The ectocervix is tan smooth and glistening with areas of pinpoint hemorrhage. The endocervical canal also has a 1.8 x 1.5 x 0.5 cm clear mucous deposit. The uterine serosa is smooth tan and glistening with multiple nodular adhesions that range in size from 0.2 to 0.4 cm in diameter. There is also an adherent tan-brown cauterized mass that is adhered to the serosa, fallopian tube, and left ovary. The right fallopian tube is also studded with multiple 0.1 to 0.3 cm nodules. The left ovary is extensively adherent to uterus. It is 4.1 x 3.2 x 2.5 cm and is tan-white and cerebriform with a disrupted capsule that has tumor grossly extending out of the capsule. The right fallopian tube is studded with grossly apparent tumor nodules that range in size from 0.1 to 0.3 cm. The left and right parametria are also grossly studded with tumor nodules that range in size from 0.1 to 0.4 cm in diameter. The tumor grossly appears to be adherent to the tube and uterus, and possibly invades the myometrium. The disrupted capsule with the tumor extruding from it is inked. The left fimbriated tube is 6.1 cm long x 0.4 cm in diameter with a pinpoint patent lumen, but the tube is stenosed and strictured. The right fimbriated tube is 4.1 cm long x 0.5 cm in diameter with a pinpoint patent lumen and a strictured tube. The right ovary is tan-white and cerebriform and is 2.5 x 1.9 x 1.2 cm. The outer surface of the right ovary does not appear to be grossly involved. The right ovary on sectioning is firm tan-white with a hemorrhagic center. The left ovary on sectioning reveals a heterogeneous parenchyma that is hemorrhagic, necrotic, and with tumor grossly extending outside the capsule.

BLOCK SUMMARY:

- B1- representative section of anterior cervix
- B2- representative section of posterior cervix
- B3- anterior full thickness endometrium
- B4- possible tumor to normal myometrium, anterior
- B5- posterior full thickness with additional section to serosal nodule
- B6- left parametrium
- B7- right parametrium
- B8- left fallopian tube
- B9- right fallopian tube
- B10-11- right ovary
- B12-15- left ovary with capsule disruption
- B17-18- adherent left ovary to uterus

[page 2 of 3]
C. "Left gutter", received fresh and placed in formalin on is a 5.5 x 4.2 x 2.5 cm fragment of yellow fibroadipose tissue with some vessels present. The specimen is firm and nodular with some areas of cauterized tissue. A representative section is submitted in C1-2.

D. "Omentum # 2", received fresh and placed in formalin on is a 12 x 11.5 x 2.4 cm aggregate of yellow fibroadipose tissue with some solid nodular areas. Representative sections are submitted in B1.

E. "Small bowel nodule", received fresh and placed in formalin on is a 5 x 2.9 x 2.4 cm fragment of tan-white tissue that is firm and has a large nodular area that covers most of the specimen. A representative section is submitted in E1.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1 (rep) - adenocarcinoma with papillary features (Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, infragastric omentectomy, removal abdominal wall mass, and optimal tumor debulking to less than 1 cm of maximal residual disease.

PATHOLOGIC STAGE (AJCC 7th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. OMENTUM (RESECTION):

INVOLVED BY HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

B. UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES (TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY):

LEFT OVARY:

TYPE: PAPILLARY SEROUS ADENOCARCINOMA. SEE NOTE.

TUMOR GRADE: HIGH GRADE.

TUMOR SIZE: 4.1 X 3.2 X 2.5 CM.

SEROSA: DISRUPTED CAPSULE WITH TUMOR PRESENT MOSTLY ON SURFACE, BUT ALSO WITHIN PARENCHYMA. SEE NOTE.

UTERUS:

CERVIX: NO DIAGNOSTIC ABNORMALITY.

ENDOMETRIUM: ATROPHIC.

LEFT FALLOPIAN TUBE: ACUTE SALPINGITIS AND SEROSITIS.

RIGHT OVARY: SURFACE SEROSAL ADHESIONS AND MESOTHELIAL HYPERPLASIA WITH DETACHED FRAGMENTS OF CARCINOMA.

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR: RIGHT FALLOPIAN TUBE, LEFT PARAMETRIUM, MYOMETRIUM AND SEROSA.

NOTE: The tumor seen in the left ovary involves predominantly the ovarian surface with only limited parenchymal involvement. Per clinical history, the

[page 3 of 3]
bulk of this tumor is present within the peritoneum/omentum. According to criteria, a tumor mass greater than 5 mm involving the ovarian parenchyma should be staged as an ovarian primary, which is the case in this material. Having said that, we suspect that in this particular case, a peritoneal origin is more likely. Clinical correlation is highly recommended.

C. LEFT GUTTER (RESECTION):

INVOLVED BY HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

D. OMENTUM #2 (RESECTION):

INVOLVED BY HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

E. SMALL BOWEL NODULE (RESECTION):

INVOLVED BY HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Attending MD:

Ordering MD:

HPA Discrepancy		
Case is (type):		

Source: NCI Genomic Data Commons file cb250160-9487-4f6c-9543-4e04669b717a (TCGA-29-A5NZ.B7F69EE0-E844-434B-A76B-390590C85864.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).